Surgical pathology report (de-identified scan), TCGA case TCGA-44-6145, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Christiana Healthcare, specimen TCGA-44-6145-01A (Primary Tumor).

[page 1 of 2]
SPECIMEN

- A. Level 12 lymph nodes
- B. Level 11 lymph nodes
- C. Level 10 lymph node
- D. Right upper lobe
- E. 2R lymph node
- F. 4R lymph node
- G. Level 7 lymph node
- H. Level 8 lymph node

CLINICAL NOTES

PRE-OP DIAGNOSIS: Lung nodule

GROSS DESCRIPTION

- A. [The specimen is] Received in formalin labeled "Level 12 lymph nodes" and consists of a red and black piece of soft tissue measuring 1.2 cm. in greatest dimension. AS-1.
- B. Received unfixed labeled "Level 11 lymph nodes" and consists of a black and e piece of soft tissue measuring 1.6 cm. in greatest dimension. [REDACTED]
- C. Received unfixed labeled "Level 10 lymph node" and consists of portions of red and l k soft tissue measuring 2 cm. in greatest aggregate dimension. [REDACTED]
- D. The specimen is received unfixed, labeled "right upper lobe" and consists of a 192 gram lung lobe measuring 12.5 x 9.5 x 3 cm. There is a contained roughly spherical mass that is subpleural and measures 2 cm. in diameter. A portion of the specimen is taken for research purposes. Sections after fixation.
- E. Received unfixed labeled "2R lymph node" and consists of three i es of yellow and red soft tissue measuring 2.5 x 3.5 x 0.4 cm. [REDACTED]
- F. Received unfixed labeled "4R lymph node" and consists of multiple pieces of pink and a soft tissue measuring 1 cm. in greatest aggregate dimension. [REDACTED]
- G. Received unfixed labeled "Level 7 lymph node" and consists of a yellow and black piece of soft tissue a ring 2.4 x 1.7 x 0.3 cm. in greatest aggregate dimension. [REDACTED]
- H. Received unfixed labeled "Level 8 lymph node" and consists of portions of pink and black so ssue measuring 1 cm. in greatest aggregate dimension. [REDACTED]

MICROSCOPIC DESCRIPTION

- A. A single lymph node is negative for malignancy
- B. A single lymph node is negative for malignancy
- C. No evidence of malignancy in multiple lymph nodes or lymph node pieces
- D.
- Tumor type: Adenocarcinoma
- Tumor grade: 2-3 out of 3
- Tumor size: 2 cm
- Bronchial resection margin: Negative for malignancy
- Pleura: Negative for malignancy
- Vascular invasion: Absent

[page 2 of 2]
Attached lymph nodes: None
pTNM Stage: T1
Non-tumorous lung: Emphysema

- E. There is no evidence of malignancy in any of 3 lymph nodes
- F. A single lymph node is negative for malignancy
- G. A single lymph node is negative for malignancy
- H. There is no evidence of malignancy in any of 4 lymph nodes

4x2,3x6

DIAGNOSIS

- A. Lymph node, level XII, biopsy:
- A single lymph node is negative for malignancy.
- B. Lymph nodes, level XI, biopsy:
- A single lymph node is negative for malignancy.
- C. Lymph node, level X, biopsy:
- There is no evidence of malignancy in multiple lymph nodes or lymph node pieces.
- D. Lung, right upper lobe, resection:
- Moderately to poorly differentiated adenocarcinoma
- E. Lymph node, 2R, biopsy:
- There is no evidence of malignancy in any of 3 lymph nodes
- F. Lymph node, 4R, biopsy:
- A single lymph node is negative for malignancy.
- G. Lymph node, level VII, biopsy:
- A single lymph node is negative for malignancy
- H. Lymph node, level VIII, biopsy:
- There is no evidence of malignancy in any of 4 lymph nodes.
-

--- End Of Report ---

Source: NCI Genomic Data Commons file 401596b8-dae1-40f7-9754-c19f85fb97f2 (TCGA-44-6145.57537882-084B-4082-BCF0-F7D297A877E6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).